Somatic mutation profile of tumor specimen TCGA-16-1045-01B (aliquot TCGA-16-1045-01B-01W-0611-08) from TCGA case TCGA-16-1045, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 49.8 years (18,195 days).
Specimen TCGA-16-1045-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4199ef27-f06b-4e1e-ac68-cbddc1424939.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-16-1045-10B (Blood Derived Normal), aliquot TCGA-16-1045-10B-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a46c5c7b-7c96-47b0-bfd9-a5a30cd99ee6

The open-access MAF lists 85 somatic variants for this specimen: 60 protein-altering or splice-affecting, 22 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 22, Nonsense Mutation 7, Frame Shift Ins 3, RNA 2, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.787A>C p.T263P | Missense Mutation (SNP) | VAF 4122/4419 reads (93%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.236); catalogued as rs1057519829, COSV51768130; ClinVar: likely pathogenic; called by mutect2, varscan2
- PTEN | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 50/121 reads (41%) | hotspot (GDC flag); catalogued as rs121909231, CM971278, COSV64288687, COSV64297951; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADD2 | c.1033G>A p.V345M | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.129); catalogued as rs782815520, COSV52468782; called by muse, mutect2, varscan2
- ARSK | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 26/332 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as rs780890433, COSV66169346; called by muse, mutect2
- BRINP1 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 47/575 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.069); catalogued as rs377626812, COSV56293961; called by muse, mutect2
- BRWD1 | c.4832C>A p.S1611* | Nonsense Mutation (SNP) | VAF 22/105 reads (21%) | catalogued as COSV60903520; called by muse, mutect2, varscan2
- CACNA1F | c.4065G>T p.Q1355H | Missense Mutation (SNP) | VAF 27/456 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.985); catalogued as COSV59903752; called by muse, mutect2
- CUX2 | c.3065C>T p.S1022L | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs756580216, COSV55647710, COSV99919073; called by muse, mutect2, varscan2
- DDC | c.551T>C p.V184A | Missense Mutation (SNP) | VAF 33/257 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV63568143; called by muse, mutect2, varscan2
- DRP2 | c.2269C>T p.R757W | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs201693431, COSV65812032; called by muse, mutect2, varscan2
- ELMO1 | c.1115C>T p.T372M | Missense Mutation (SNP) | VAF 86/257 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.041); catalogued as rs748062510, COSV60299509; called by muse, mutect2, varscan2
- FAM122A | c.650T>C p.F217S | Missense Mutation (SNP) | VAF 83/212 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.201); catalogued as COSV55258817; called by muse, mutect2, varscan2
- FLNB | c.6211G>A p.V2071I | Missense Mutation (SNP) | VAF 21/333 reads (6%) | SIFT tolerated (1); PolyPhen probably damaging (0.997); catalogued as rs201831615; called by muse, mutect2
- GADL1 | c.749A>T p.E250V | Missense Mutation (SNP) | VAF 50/243 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV56986676; called by muse, mutect2, varscan2
- HUWE1 | c.4963C>T p.R1655* | Nonsense Mutation (SNP) | VAF 462/885 reads (52%) | catalogued as COSV53365799; called by muse, mutect2, varscan2
- KLF7 | c.419C>T p.S140L | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.926); catalogued as rs1231413667, COSV58743962; called by muse, mutect2, varscan2
- LHFPL2 | c.530G>A p.G177E | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); catalogued as COSV66713436, COSV66716551; called by muse, mutect2, varscan2
- LONRF3 | c.1723T>A p.F575I (on ENST00000371628 / NM_001031855.3; = p.F534I on NM_024778.5) | Missense Mutation (SNP) | VAF 415/768 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59157248; called by muse, mutect2, varscan2
- LRRC7 | c.1036T>C p.C346R (on ENST00000651989 / NM_001370785.2; = p.C313R on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.898); catalogued as rs761863170, COSV50644130; called by muse, varscan2
- NFIL3 | c.745G>A p.G249R | Missense Mutation (SNP) | VAF 92/449 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); catalogued as COSV52684863; called by muse, mutect2, varscan2
- OGT | c.1587C>A p.N529K | Missense Mutation (SNP) | VAF 113/474 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.287); catalogued as COSV65482804; called by muse, mutect2, varscan2
- OR10AG1 | c.726C>A p.F242L | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); catalogued as COSV56633688, COSV56635152; called by mutect2, varscan2
- OR1G1 | c.925A>G p.K309E | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.206); catalogued as COSV61030687; called by muse, mutect2, varscan2
- PCCB | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 142/466 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV52448467; called by muse, mutect2, varscan2
- PHACTR1 | c.759dup p.P254Afs*78 | Frame Shift Ins (INS) | VAF 12/83 reads (14%) | catalogued as rs749326031; called by mutect2, varscan2
- PHLDB2 | c.1646G>A p.R549Q | Missense Mutation (SNP) | VAF 34/179 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as rs1301070338, COSV67316478; called by muse, mutect2, varscan2
- PTPRC | c.61G>T p.V21L | Missense Mutation (SNP) | VAF 46/381 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.176); catalogued as rs1288480100, COSV61421267; called by muse, mutect2, varscan2
- RIPOR1 | c.162dup p.A55Rfs*67 (on ENST00000379312 / NM_001193522.2; = p.A51Rfs*67 on NM_024519.4) | Frame Shift Ins (INS) | VAF 6/35 reads (17%) | catalogued as rs763705850; called by mutect2, pindel, varscan2
- SAGE1 | c.944T>G p.V315G | Missense Mutation (SNP) | VAF 57/306 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV61018612; called by muse, mutect2, varscan2
- SEC23B | c.2049C>A p.F683L | Missense Mutation (SNP) | VAF 165/945 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.123); catalogued as COSV52724322; called by muse, mutect2, varscan2
- SGMS2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 100/447 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV62989863; called by muse, mutect2, varscan2
- SLC10A4 | c.538G>A p.G180S | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56720052; called by muse, mutect2, varscan2
- SLC6A16 | c.1039T>A p.L347M | Missense Mutation (SNP) | VAF 43/184 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV60030880; called by muse, mutect2, varscan2
- SLC6A4 | c.632A>C p.N211T | Missense Mutation (SNP) | VAF 49/172 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV55570078; called by muse, mutect2, varscan2
- SSH1 | c.244A>T p.I82F | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as COSV58460707; called by muse, mutect2, varscan2
- TDP2 | c.196G>A p.V66M | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV57765845; called by muse, mutect2, varscan2
- TEAD2 | c.883dup p.H295Pfs*19 | Frame Shift Ins (INS) | VAF 36/288 reads (13%) | catalogued as rs763321097; called by mutect2, varscan2
- TENT5C | c.1087G>A p.V363I | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.685); catalogued as rs773285739, COSV65615907; called by muse, mutect2, varscan2
- TMEM255A | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 143/483 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1556019904, COSV59028981; called by muse, mutect2, varscan2
- TNS4 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV54188377; called by muse, mutect2, varscan2
- TREML4 | c.10G>A p.G4S | Missense Mutation (SNP) | VAF 11/12 reads (92%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.005); catalogued as COSV58386571; called by muse, mutect2, varscan2
- TTN | c.43318G>T p.D14440Y (on ENST00000591111; = p.D7016Y on NM_003319.4) | Missense Mutation (SNP) | VAF 18/570 reads (3%) | PolyPhen benign (0.311); catalogued as COSV60171020; called by muse, mutect2
- UHRF1BP1 | c.4159G>A p.V1387M | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV51961038; called by muse, mutect2, varscan2
- VWF | c.8336C>T p.T2779M | Missense Mutation (SNP) | VAF 54/208 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as rs374314985; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR11 | c.1868A>G p.N623S | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.062); catalogued as COSV54793676; called by muse, mutect2, varscan2
- YTHDC1 | c.1711G>T p.E571* (on ENST00000344157 / NM_001031732.4; = p.E553* on NM_133370.4) | Nonsense Mutation (SNP) | VAF 44/134 reads (33%) | catalogued as COSV60009598, COSV60012310; called by muse, mutect2, varscan2
- ZFC3H1 | c.3406A>G p.M1136V | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV66436253; called by muse, mutect2, varscan2
- ABCA1 | c.674C>G p.A225G | Missense Mutation (SNP) | VAF 101/460 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- ABCC2 | c.4282C>A p.H1428N | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- CACNA1E | c.357del p.M120Cfs*67 | Frame Shift Del (DEL) | VAF 93/338 reads (28%) | called by mutect2, pindel, varscan2
- CACNA1E | c.398G>C p.G133A | Missense Mutation (SNP) | VAF 19/706 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.621); called by muse, mutect2
- EPHB1 | c.333C>A p.N111K | Missense Mutation (SNP) | VAF 30/1134 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- FAM47B | c.373C>G p.L125V | Missense Mutation (SNP) | VAF 53/425 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- FGFR2 | c.781G>T p.G261* | Nonsense Mutation (SNP) | VAF 28/478 reads (6%) | called by muse, mutect2
- NEU1 | c.68G>A p.W23* | Nonsense Mutation (SNP) | VAF 7/82 reads (9%) | called by muse, mutect2
- PBX2 | c.760C>T p.Q254* | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- PCDHGC5 | c.2368C>A p.L790I | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.82); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- PMFBP1 | c.2936G>A p.C979Y (on ENST00000537465; = p.C974Y on NM_031293.3) | Missense Mutation (SNP) | VAF 37/214 reads (17%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PRKDC | c.6562G>A p.E2188K | Missense Mutation (SNP) | VAF 66/174 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.437); called by muse, varscan2
- ZNF609 | c.789C>A p.H263Q | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, varscan2
- ANG | c.240C>A p.I80= | Silent (SNP) | VAF 21/494 reads (4%) | catalogued as rs1566602528; called by muse, mutect2
- ATIC | c.363G>A p.V121= | Silent (SNP) | VAF 26/384 reads (7%) | called by muse, mutect2
- CACNA2D1 | c.3102G>A p.A1034= (on ENST00000356253 / NM_001366867.1; = p.A1022= on NM_000722.4) | Silent (SNP) | VAF 72/222 reads (32%) | catalogued as rs780560452, COSV62389499, COSV62394110; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4596G>A p.E1532= | Silent (SNP) | VAF 12/113 reads (11%) | called by muse, mutect2
- DMBX1 | c.96G>A p.Q32= | Silent (SNP) | VAF 36/68 reads (53%) | catalogued as COSV63602662; called by muse, mutect2, varscan2
- ELMO1 | c.1758G>A p.L586= | Silent (SNP) | VAF 14/202 reads (7%) | catalogued as COSV60327125; called by muse, mutect2
- EYA4 | c.1770C>T p.C590= (on ENST00000531901 / NM_001301013.1; = p.C584= on NM_004100.5) | Silent (SNP) | VAF 80/416 reads (19%) | catalogued as rs771515273; called by muse, mutect2, varscan2
- GLUD2 | c.432G>A p.T144= | Silent (SNP) | VAF 29/149 reads (19%) | catalogued as rs772586560, COSV60151620; called by muse, mutect2, varscan2
- GYS2 | c.279C>T p.D93= | Silent (SNP) | VAF 29/130 reads (22%) | catalogued as rs779704436, COSV53926335; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IL5RA | c.444A>G p.S148= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as COSV56527021; called by muse, mutect2, varscan2
- KIR3DL1 | c.138T>A p.T46= | Silent (SNP) | VAF 51/329 reads (16%) | called by muse, varscan2
- LRCH4 | c.882C>T p.Y294= | Silent (SNP) | VAF 29/262 reads (11%) | catalogued as rs150987161; called by muse, mutect2, varscan2
- MECOM | c.69C>T p.C23= (on ENST00000468789 / NM_001105078.4; = p.C211= on NM_004991.4) | Silent (SNP) | VAF 224/638 reads (35%) | catalogued as rs188482846, COSV52976360; called by muse, mutect2, varscan2
- OCA2 | c.441G>T p.L147= | Silent (SNP) | VAF 11/220 reads (5%) | called by muse, mutect2
- OR51A2 | c.798C>T p.A266= | Silent (SNP) | VAF 28/160 reads (18%) | catalogued as rs1412631339, COSV66748208; called by muse, mutect2, varscan2
- PON1 | c.597T>A p.G199= | Silent (SNP) | VAF 111/375 reads (30%) | catalogued as COSV55934082; called by muse, varscan2
- SKOR1 | c.693C>T p.D231= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV58248905; called by mutect2, varscan2
- SLC9A8 | c.1581C>T p.F527= | Silent (SNP) | VAF 5/71 reads (7%) | catalogued as rs1441932016, COSV64287043; called by muse, mutect2
- TPR | c.1239A>G p.K413= | Silent (SNP) | VAF 54/150 reads (36%) | catalogued as COSV66605445; called by muse, mutect2, varscan2
- TRIM5 | c.540C>T p.N180= | Silent (SNP) | VAF 57/261 reads (22%) | catalogued as rs182373551, COSV59902368; called by muse, mutect2, varscan2
- ZNF140 | c.1122A>G p.Q374= | Silent (SNP) | VAF 45/189 reads (24%) | catalogued as rs780929807, COSV60580136; called by muse, mutect2, varscan2
- ZNF521 | c.1041C>T p.V347= | Silent (SNP) | VAF 211/826 reads (26%) | catalogued as COSV64122430, COSV64132370; called by muse, mutect2, varscan2
- AC005863.1 | n.108C>T | RNA (SNP) | VAF 36/135 reads (27%) | catalogued as rs1481053438; called by muse, varscan2
- GPR35 | c.-452-113C>T | Intron (SNP) | VAF 8/36 reads (22%) | catalogued as COSV54387481; called by muse, mutect2, varscan2
- WASF4P | n.839A>G | RNA (SNP) | VAF 33/126 reads (26%) | called by muse, mutect2, varscan2
